Surgical pathology report (de-identified scan), TCGA case TCGA-UT-A88G, project TCGA-MESO (Mesothelioma), tissue source site Asbestos Diseases Research Institute, specimen TCGA-UT-A88G-01B (Primary Tumor).

STUDY ID:

DOB :
Sex : Male
Ph :

Requested :
Collected :
Received :
Printed :

*** The following test has been amended ***

HISTOPATHOLOGY REPORT :

CLINICAL NOTES:

Asbestos +ve history. Right pleural effusion ? meso.

MACROSCOPIC:

'Parietal pleura'. The specimen consists of multiple pink pieces of tissue measuring between 3mm and 10mm in maximal dimension. Several of the larger pieces bare firm pink nodules measuring between 3mm and 7mm in maximal dimension. Representative sections. (Block A - 6p, B - 5p)

MICROSCOPIC:

The specimen consists of portions of pleura which show a surface micropapillary and infiltrating malignant tumour with features which favour malignant mesothelioma of epithelial type. On the surface of the pleura the malignant cells are arranged in microacinar groups and micropapillary tufts and the constituent cells have enlarged nuclei with focally prominent nucleoli with a variable amount of eosinophilic to clear cytoplasm. The cells infiltrate thickened fibrotic pleura and encroach on pleural fat. In some areas the stroma is slightly myxoid and contains elongated spindle cells raising the possibility of a biphasic component. There are scattered psammoma bodies.

No intracytoplasmic mucin is seen on PAS stain.
Immunohistochemistry will be performed and a further report will follow.

DIAGNOSIS:

RIGHT PARIETAL PLEURA - MALIGNANT INFILTRATE, FAVOUR MALIGNANT MESOTHELIOMA

Reported by

SUPPLEMENTARY REPORT dated

Immunohistochemistry has been performed.

The surface micropapillary component and the epithelioid component shows strong positive staining for calretinin. This stain also shows positive staining of the spindle cells in the desmoplastic component and the deeper levels highlight a greater proportion of this component. The stains for CK 5/6 and HBME1 also show a similar pattern of staining. The epithelial component stains positively for the lymphatic marker with no significant staining for CEA, TTF-1 or MOC31.

The pattern of differentiation and the Immunohistochemical profile are consistent with malignant mesothelioma of epithelial and biphasic types.

DIAGNOSIS:

RIGHT PARIETAL PLEURA - MALIGNANT MESOTHELIOMA, EPITHELIAL AND BIPHASIC TYPES

Reported by

*** End of amendment ***

Surgeon
Use

☐ Normo

☐ No Action
File

☐ Contact
Patient

☐ See
Patient

☐ See File

☐ Continue
Treatment

Signed

Date

FINAL REPORT

Source: NCI Genomic Data Commons file 1028225c-7ac6-4382-8aa9-59737ff344fc (TCGA-UT-A88G.0A21CA31-B711-4E7D-8616-7F0A064C1A03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).